CCDI case PBBXRW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/cf0a00b2-ecd6-4bf6-82c7-4631d0174dcc

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 7.5 years (2,722 days).

Biospecimens (3 samples)
- Sample 0DK1V6: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DK1WD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DK1WJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
